Somatic mutation profile of tumor specimen TCGA-CN-A497-01A (aliquot TCGA-CN-A497-01A-11D-A24D-08) from TCGA case TCGA-CN-A497, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.8 years (23,310 days).
Specimen TCGA-CN-A497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a81daad-2a7b-43b7-928c-31d4ffc064f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A497-10A (Blood Derived Normal), aliquot TCGA-CN-A497-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b4f1610-fe99-4f8e-9a74-ae702309f59c

The open-access MAF lists 380 somatic variants for this specimen: 295 protein-altering or splice-affecting, 79 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 79, Nonsense Mutation 14, Splice Site 11, Frame Shift Del 11, RNA 3, Intron 3, Frame Shift Ins 3, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99787628; called by muse, varscan2
- ABCA13 | c.14528G>A p.R4843H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs752658494, COSV68947083; called by muse, mutect2, varscan2
- ACTC1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.92); catalogued as CM1010343, COSV99291523; called by muse, mutect2, varscan2
- ADAM22 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs553357216, COSV99715318; called by muse, mutect2, varscan2
- ADCY5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV71901346; called by muse, mutect2, varscan2
- ADGRB3 | c.2512G>C p.G838R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99482996; called by muse, mutect2, varscan2
- ADGRF1 | c.1690A>T p.T564S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as COSV99346845, COSV99347037; called by muse, mutect2, varscan2
- ADGRL2 | c.2493G>T p.M831I (on ENST00000370717 / NM_001366005.1; = p.M818I on NM_012302.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99586600; called by muse, mutect2, varscan2
- ADGRV1 | c.15337C>G p.L5113V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101315268; called by muse, mutect2, varscan2
- AKAP6 | c.6478G>A p.V2160I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99797249; called by muse, mutect2
- AKAP9 | c.3544A>T p.K1182* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100661746; called by muse, mutect2, varscan2
- ANO5 | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100201259; called by muse, mutect2, varscan2
- AP002512.3 | c.7A>T p.N3Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); catalogued as COSV100392229; called by muse, mutect2, varscan2
- ASCL1 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99901849; called by muse, mutect2, varscan2
- ATP13A4 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99793879; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2012T>A p.L671Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV100022416; called by muse, mutect2, varscan2
- AXIN1 | c.879-1G>A p.X293_splice | Splice Site (SNP) | VAF 23/36 reads (64%) | catalogued as COSV99249017; called by muse, mutect2, varscan2
- B4GALNT3 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 58/85 reads (68%) | catalogued as COSV99842188; called by muse, varscan2
- BAIAP3 | c.2426A>G p.N809S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1446583818, COSV99136088; called by muse, mutect2, varscan2
- BCLAF1 | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV100786357; called by muse, mutect2, varscan2
- BEND2 | c.895C>A p.H299N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101191661, COSV66216410; called by muse, mutect2, varscan2
- BHLHE41 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1565665798, COSV99658168; called by muse, mutect2, varscan2
- BHMT2 | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV99669836; called by muse, mutect2, varscan2
- BICC1 | c.1528+1G>A p.X510_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99570038; called by muse, mutect2, varscan2
- BOC | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1323189254, COSV99847777; called by muse, mutect2, varscan2
- BSND | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100987593; called by muse, mutect2, varscan2
- C12orf43 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs199680654, COSV99984369; called by muse, mutect2, varscan2
- C12orf60 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.082); catalogued as COSV99966758; called by muse, mutect2, varscan2
- C1QTNF3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99180675; called by muse, mutect2, varscan2
- C6orf58 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV100314629; called by muse, mutect2, varscan2
- CAPN6 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100136600; called by muse, mutect2, varscan2
- CCSER2 | c.2297A>G p.Y766C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as rs1218691901, COSV99825293; called by muse, mutect2, varscan2
- CD163 | c.3053G>C p.C1018S | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775568; called by muse, mutect2, varscan2
- CD93 | c.934C>A p.R312S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs762071141, COSV55669405, COSV99848760; called by muse, mutect2
- CDH10 | c.2304G>T p.W768C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100049554; called by muse, mutect2, varscan2
- CDH10 | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100049556, COSV52573536; called by muse, mutect2, varscan2
- CDH18 | c.2344G>T p.G782* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99931126; called by muse, mutect2, varscan2
- CDH18 | c.1789G>T p.V597L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99931129; called by muse, mutect2, varscan2
- CEP112 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101210357; called by muse, mutect2, varscan2
- CFAP46 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs536559191, COSV100886078; called by muse, mutect2, varscan2
- CHML | c.1649G>A p.W550* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100086855; called by muse, mutect2, varscan2
- CLVS1 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV100369250; called by muse, mutect2, varscan2
- CNTN3 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV55181858; called by muse, mutect2, varscan2
- CNTN4 | c.1036A>C p.T346P | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV100638633; called by mutect2, varscan2
- COL11A1 | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100614316; called by muse, mutect2, varscan2
- COL11A1 | c.1517G>C p.G506A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100614319, COSV104421818, COSV62202227; called by muse, mutect2, varscan2
- COL11A1 | c.1280A>C p.Q427P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100614321, COSV62181198; called by muse, varscan2
- CRACDL | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV101193881; called by muse, mutect2, varscan2
- CSMD3 | c.9122G>T p.W3041L (on ENST00000297405 / NM_001363185.1; = p.W2872L on NM_052900.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99820271; called by muse, mutect2, varscan2
- CSMD3 | c.4565G>T p.S1522I (on ENST00000297405 / NM_001363185.1; = p.S1418I on NM_052900.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV52330099, COSV99829437; called by muse, mutect2, varscan2
- CSMD3 | c.4565-1G>A p.X1522_splice (on ENST00000297405 / NM_001363185.1; = p.X1418_splice on NM_052900.3) | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV52198204, COSV99820276; called by muse, mutect2, varscan2
- CSTF3 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV100123651; called by muse, mutect2, varscan2
- CTCFL | c.85del p.E29Rfs*52 | Frame Shift Del (DEL) | VAF 52/218 reads (24%) | catalogued as COSV99713224; called by mutect2, pindel, varscan2
- CUL3 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52373053; called by muse, varscan2
- DAPK1 | c.4063C>T p.P1355S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs1234077570, COSV100800662; called by muse, mutect2, varscan2
- DCP1B | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV99767058; called by muse, mutect2, varscan2
- DENND1C | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101200124; called by muse, mutect2, varscan2
- DIO2 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101375798; called by muse, mutect2, varscan2
- DNER | c.560T>A p.V187E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100518012; called by mutect2, varscan2
- DOK5 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); catalogued as COSV99373045; called by muse, mutect2, varscan2
- DUOX2 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99972630; called by muse, mutect2, varscan2
- EEF1A1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); catalogued as COSV100303109; called by muse, mutect2, varscan2
- EFCAB5 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs553413830, COSV57933864; called by muse, mutect2, varscan2
- EGLN3 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as COSV99164277; called by muse, mutect2, varscan2
- EML1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.439); catalogued as COSV51752853, COSV99214310; called by muse, mutect2, varscan2
- EPHA5 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99894947; called by muse, mutect2, varscan2
- EPHA6 | c.1250C>G p.P417R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101060507, COSV67582509; called by muse, mutect2, varscan2
- ERP27 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV99844119; called by muse, mutect2, varscan2
- EXO5 | c.932A>T p.K311I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99591150; called by muse, mutect2, varscan2
- EXOC6 | c.1706C>G p.T569S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99591215; called by muse, mutect2, varscan2
- FAM13C | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99512828; called by muse, mutect2, varscan2
- FAM187B | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV100219908; called by muse, mutect2, varscan2
- FAM50B | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100976481; called by muse, mutect2, varscan2
- FCRL5 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV62517578; called by muse, mutect2, varscan2
- FER1L6 | c.3992C>A p.P1331H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101205236; called by muse, mutect2, varscan2
- FMO1 | c.701T>G p.V234G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100707669, COSV61446225; called by muse, mutect2, varscan2
- FNDC1 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51946222, COSV99794506; called by muse, mutect2, varscan2
- FRYL | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99975204; called by muse, mutect2, varscan2
- FSHR | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as COSV100436296, COSV58618781; called by muse, mutect2, varscan2
- GAD2 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV52155273, COSV99392246; called by muse, mutect2, varscan2
- GBF1 | c.2018C>G p.A673G (on ENST00000369983 / NM_001377137.1; = p.A672G on NM_004193.3) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1327123598, COSV100890229; called by muse, mutect2, varscan2
- GCSAM | c.111C>A p.H37Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.234); catalogued as COSV100453079; called by muse, mutect2, varscan2
- GDF6 | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99747463; called by muse, mutect2, varscan2
- GLG1 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV52664938, COSV99215095; called by muse, mutect2, varscan2
- GLIS3 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100173028; called by muse, mutect2, varscan2
- GNG13 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99241880; called by muse, mutect2, varscan2
- GOSR1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773900657, COSV99853477; called by muse, mutect2, varscan2
- GPA33 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100900852; called by muse, mutect2, varscan2
- GPHN | c.1594G>A p.A532T (on ENST00000315266 / NM_001377519.1; = p.A565T on NM_020806.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV100014812; called by muse, mutect2, varscan2
- GPR142 | c.1181T>A p.L394Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170628; called by muse, varscan2
- GPR15 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV52521101, COSV99423578; called by muse, mutect2, varscan2
- GPR37 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV58255500; called by muse, varscan2
- GRIP1 | c.2582G>T p.G861V (on ENST00000359742 / NM_001379345.1; = p.G809V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99667461; called by muse, mutect2, varscan2
- GUCY1A2 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99972079, COSV99972106; called by muse, mutect2, varscan2
- H4C4 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100534353; called by muse, mutect2, varscan2
- HAPLN4 | c.1002C>G p.N334K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV99363519; called by muse, mutect2
- HDAC9 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as COSV101285601; called by muse, mutect2, varscan2
- HNF4A | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs537703038, COSV100290908; called by muse, mutect2, varscan2
- HTR1B | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100885290; called by muse, mutect2, varscan2
- IFI44 | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100877243; called by mutect2, varscan2
- IKZF1 | c.1328A>T p.E443V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.582); catalogued as COSV100497797; called by muse, mutect2, varscan2
- IL21R | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100559717; called by muse, mutect2, varscan2
- IPO11 | c.2341G>C p.G781R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV100320129; called by muse, mutect2, varscan2
- IPO13 | c.2855G>C p.R952P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664171; called by muse, mutect2, varscan2
- IQCH | c.1867G>T p.V623F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100245222; called by muse, mutect2, varscan2
- ITGA4 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99275520; called by muse, mutect2, varscan2
- KCNH8 | c.3301G>T p.D1101Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764065528, COSV100107976; called by muse, mutect2, varscan2
- KCNN2 | c.1423C>A p.Q475K (on ENST00000264773; = p.Q687K on NM_021614.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV99298450; called by muse, mutect2, varscan2
- KIAA0408 | c.499-2A>G p.X167_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100846709; called by muse, mutect2, varscan2
- KIF14 | c.3582G>A p.M1194I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs1191938562, COSV66264239; called by muse, mutect2, varscan2
- KIT | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as COSV99852606; called by muse, mutect2, varscan2
- KRT33A | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV99144761; called by muse, mutect2, varscan2
- KRTAP13-1 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV62664141; called by muse, mutect2, varscan2
- KRTAP5-11 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100651636; called by muse, mutect2, varscan2
- KRTAP5-2 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 57/161 reads (35%) | PolyPhen probably damaging (0.982); catalogued as COSV69015408; called by muse, mutect2, varscan2
- KYNU | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51582727, COSV99932611; called by muse, mutect2
- LAMA1 | c.8035C>A p.P2679T | Missense Mutation (SNP) | VAF 206/240 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV67543972; called by muse, mutect2, varscan2
- LAMA2 | c.9105C>A p.H3035Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV101369808; called by muse, mutect2, varscan2
- LCP1 | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100549567; called by muse, mutect2, varscan2
- LHX8 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.247); catalogued as COSV53955022, COSV99634189; called by muse, mutect2, varscan2
- LILRA5 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100006647; called by muse, mutect2
- LIPC | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100134039, COSV100134456; called by muse, mutect2, varscan2
- LRRC3B | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67520786; called by muse, mutect2, varscan2
- MAF1 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075214; called by muse, mutect2, varscan2
- MAGEB6 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV100983628; called by muse, mutect2, varscan2
- MAGI1 | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100438815; called by muse, mutect2, varscan2
- MAP3K21 | c.2306A>G p.K769R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100786058; called by muse, mutect2, varscan2
- MAP3K8 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs1457067245, COSV53919353; called by muse, mutect2, varscan2
- MCF2 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100644306; called by muse, mutect2, varscan2
- MEGF6 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs759373586, COSV99619106; called by muse, mutect2, varscan2
- METTL8 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.605); catalogued as rs772797511, COSV100930935; called by muse, mutect2, varscan2
- MINAR1 | c.2222G>T p.R741L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs753895773, COSV59585126, COSV59585736; called by muse, mutect2, varscan2
- MRGPRX1 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100245786, COSV57107242, COSV57107590; called by muse, mutect2, varscan2
- MRGPRX4 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049596; called by muse, mutect2, varscan2
- MRPL19 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100718480, COSV62567826; called by muse, mutect2, varscan2
- MUC16 | c.24610A>G p.T8204A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV101197313; called by muse, mutect2, varscan2
- MUC5AC | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); catalogued as COSV100650474; called by muse, mutect2
- MYBL1 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101576442; called by muse, mutect2, varscan2
- MYBPC1 | c.781G>T p.A261S (on ENST00000550270 / NM_206820.2; = p.A286S on NM_002465.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100637669; called by muse, mutect2, varscan2
- MYH2 | c.3135G>T p.E1045D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99818964; called by muse, mutect2, varscan2
- MYH6 | c.1556A>G p.Q519R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as COSV100676136; called by muse, mutect2, varscan2
- MYLK | c.-2C>A | Splice Region (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100658316; called by muse, mutect2, varscan2
- MYOM1 | c.1138C>A p.R380S | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV99864775; called by muse, mutect2, varscan2
- NAA25 | c.2132A>T p.N711I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99927166; called by muse, mutect2, varscan2
- NEXMIF | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99279245; called by muse, mutect2
- NOC2L | c.1218G>C p.W406C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750154349, COSV100497750, COSV100497995; called by muse, mutect2, varscan2
- NPC1L1 | c.3929C>G p.A1310G | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.313); catalogued as COSV99202545; called by muse, mutect2, varscan2
- NRP1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.364); catalogued as COSV99587469; called by muse, mutect2, varscan2
- NSD1 | c.4171G>T p.E1391* | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV61783997; called by muse, mutect2, varscan2
- NSD1 | c.6095G>A p.W2032* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as CM074965, COSV100728257; called by muse, mutect2, varscan2
- NTN1 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99431987; called by muse, mutect2, varscan2
- NTNG1 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634885; called by muse, mutect2, varscan2
- ODAPH | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.372); catalogued as COSV100290030; called by muse, mutect2, varscan2
- OGFRL1 | c.862A>G p.R288G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100965689; called by muse, mutect2, varscan2
- OLFM3 | c.1116C>A p.S372R (on ENST00000338858 / NM_001288821.1; = p.S352R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs764971026, COSV100128674; called by muse, mutect2, varscan2
- OR10A7 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV100406485; called by muse, mutect2, varscan2
- OR2L3 | c.454T>A p.S152T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV100741880, COSV63456619; called by muse, varscan2
- OR2T4 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV63545308; called by muse, mutect2, varscan2
- OR52L1 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175971, COSV100176126; called by muse, mutect2, varscan2
- OR5M11 | c.841A>T p.S281C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs751950204, COSV101602009; called by muse, mutect2, varscan2
- OR5T2 | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100506732, COSV100507002; called by muse, mutect2, varscan2
- OR6C70 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100524302, COSV59245072; called by muse, mutect2, varscan2
- OR6S1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV57839236; called by muse, mutect2, varscan2
- PADI1 | c.1766T>C p.M589T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100968947; called by muse, mutect2, varscan2
- PAX1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101270163, COSV68271869; called by muse, mutect2, varscan2
- PCDH9 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100117266; called by muse, mutect2, varscan2
- PCDHA3 | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as rs782575320, COSV100793049; called by muse, mutect2, varscan2
- PCDHA9 | c.1159T>C p.C387R | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100968877; called by muse, mutect2, varscan2
- PCDHB6 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99169864; called by muse, mutect2, varscan2
- PCDHGA6 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV54055692; called by muse, mutect2, varscan2
- PCDHGB1 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99527993; called by muse, mutect2, varscan2
- PCLO | c.6245C>A p.P2082Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100426069; called by muse, mutect2, varscan2
- PFKP | c.1498A>G p.I500V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV101126813; called by muse, mutect2, varscan2
- PGBD1 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99459526; called by muse, mutect2, varscan2
- PHLDB1 | c.471C>G p.S157R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV100616152; called by muse, mutect2, varscan2
- PKHD1L1 | c.2387T>A p.L796Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV101005029; called by muse, mutect2, varscan2
- PKHD1L1 | c.9847G>A p.G3283S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101005030; called by muse, mutect2, varscan2
- PKHD1L1 | c.9848G>A p.G3283D | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV101005031, COSV65751921; called by muse, mutect2, varscan2
- PLA2G7 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1336163707, COSV99221020; called by muse, mutect2, varscan2
- PLCH2 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV99615249; called by muse, mutect2, varscan2
- PLEK2 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99371503; called by muse, mutect2, varscan2
- PLEKHA5 | c.1241T>A p.L414* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100163209; called by muse, mutect2, varscan2
- PLEKHM3 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as COSV101216135; called by muse, mutect2, varscan2
- PLSCR4 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV100724068; called by muse, mutect2, varscan2
- PLXNA1 | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302021; called by muse, mutect2, varscan2
- PLXNA2 | c.4518C>G p.N1506K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.605); catalogued as COSV100884854; called by muse, mutect2, varscan2
- PLXNA2 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884855, COSV65442188; called by muse, mutect2, varscan2
- POU4F3 | c.887A>G p.Q296R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100046743; called by muse, mutect2, varscan2
- PPP4R4 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428145; called by muse, mutect2, varscan2
- PREX1 | c.2022C>G p.D674E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100905979; called by muse, mutect2, varscan2
- PRKCB | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV57767165, COSV57769485; called by muse, varscan2
- PTPN23 | c.2156G>T p.R719L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV99650046, COSV99650518; called by muse, varscan2
- PTPRB | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100545705; called by muse, mutect2, varscan2
- PXDNL | c.2440T>A p.L814M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.859); catalogued as COSV100680258, COSV100682747; called by muse, mutect2
- PYGO1 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100114362; called by muse, mutect2, varscan2
- QTRT1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV99138980; called by muse, mutect2, varscan2
- RBM18 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1223633773, COSV101313765; called by muse, mutect2, varscan2
- RINT1 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99994138; called by muse, mutect2, varscan2
- RIPPLY1 | c.287A>T p.H96L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52174689, COSV99343578; called by muse, mutect2, varscan2
- RNF20 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100874288; called by muse, mutect2, varscan2
- RYR2 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100767077; called by muse, mutect2, varscan2
- S1PR1 | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59513453; called by muse, mutect2, varscan2
- SCGB1D1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1339636532, COSV100086585; called by muse, mutect2, varscan2
- SCNN1G | c.1075C>T p.L359= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100263785, COSV100263892; called by muse, mutect2, varscan2
- SESN3 | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99565145; called by muse, mutect2, varscan2
- SIM1 | c.1895A>G p.H632R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99491713; called by muse, mutect2, varscan2
- SLC12A2 | c.2327G>T p.R776L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.672); catalogued as COSV52477470; called by muse, mutect2, varscan2
- SLC15A4 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV57160920, COSV99903325; called by muse, mutect2, varscan2
- SLC16A14 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725053; called by muse, mutect2, varscan2
- SLC25A32 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884114; called by muse, mutect2, varscan2
- SLC2A2 | c.443del p.G148Dfs*7 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV58585469; called by mutect2, pindel, varscan2
- SLC35G3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV99268040; called by muse, mutect2, varscan2
- SLC39A12 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101069768, COSV66198279; called by muse, mutect2, varscan2
- SLC5A12 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744203; called by muse, mutect2, varscan2
- SLCO1A2 | c.1281A>T p.Q427H | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100261137; called by muse, mutect2, varscan2
- SMAD3 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100528546, COSV100529104; called by muse, mutect2, varscan2
- SMOC1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100734195; called by muse, mutect2, varscan2
- SNCAIP | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99746508; called by muse, mutect2, varscan2
- SNTG1 | c.1450G>C p.A484P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52430544, COSV99380198, COSV99385610; called by muse, mutect2, varscan2
- SNX14 | c.940C>G p.P314A (on ENST00000314673 / NM_001350535.1; = p.P270A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs774511158, COSV100121363, COSV59011140; called by muse, mutect2
- SOGA1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200205394, COSV99412356; called by muse, mutect2, varscan2
- SPATA16 | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100650745; called by muse, mutect2, varscan2
- SPATA16 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV100650746, COSV63531908; called by muse, mutect2, varscan2
- SPATC1 | c.1393C>A p.R465S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101084542; called by muse, mutect2, varscan2
- SPEG | c.3338G>T p.R1113L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100402952; called by muse, mutect2, varscan2
- SPTB | c.5166T>G p.F1722L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV101071842; called by muse, mutect2, varscan2
- STK31 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100669033; called by mutect2, varscan2
- SULT1C2 | c.47T>A p.V16E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99264905; called by muse, mutect2, varscan2
- SUPT6H | c.4806+1G>T p.X1602_splice | Splice Site (SNP) | VAF 27/66 reads (41%) | catalogued as COSV99972451; called by muse, mutect2, varscan2
- SYNE1 | c.21493G>A p.A7165T (on ENST00000367255 / NM_182961.4; = p.A7094T on NM_033071.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99549301; called by muse, mutect2, varscan2
- SYNE1 | c.21005G>T p.S7002I (on ENST00000367255 / NM_182961.4; = p.S6931I on NM_033071.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99549309; called by muse, mutect2, varscan2
- SYNE1 | c.10582C>A p.H3528N (on ENST00000367255 / NM_182961.4; = p.H3535N on NM_033071.3) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV99549314; called by muse, mutect2, varscan2
- SYNE1 | c.3997C>A p.R1333S (on ENST00000367255 / NM_182961.4; = p.R1340S on NM_033071.3) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV54900080, COSV99549323; called by muse, mutect2, varscan2
- SYNJ1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV59143697; called by muse, mutect2, varscan2
- SYT15 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV100970145; called by mutect2, varscan2
- TAOK2 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99663573; called by muse, mutect2, varscan2
- TAS2R8 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99553488; called by muse, mutect2
- TBCK | c.1237C>T p.H413Y (on ENST00000273980 / NM_001163436.4; = p.H350Y on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV99911877; called by muse, mutect2, varscan2
- TEKT4 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV99726036; called by muse, mutect2, varscan2
- TENT4A | c.1009-2A>T p.X337_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100048478; called by muse, mutect2, varscan2
- TERF1 | c.1168A>T p.N390Y (on ENST00000276603 / NM_017489.3; = p.N370Y on NM_003218.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99400765; called by muse, mutect2, varscan2
- TFAP2B | c.1173C>G p.I391M | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV99539506, COSV99540101; called by muse, mutect2, varscan2
- TFDP3 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100033130; called by muse, mutect2, varscan2
- TGM6 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.174); catalogued as COSV99171646; called by muse, mutect2, varscan2
- THSD7A | c.4696G>T p.D1566Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV101349148; called by muse, mutect2, varscan2
- TLE6 | c.1315C>T p.P439S (on ENST00000246112 / NM_001143986.2; = p.P316S on NM_024760.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99857816; called by muse, mutect2, varscan2
- TM7SF2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.315); catalogued as COSV99659469; called by muse, mutect2, varscan2
- TMCC1 | c.1768A>G p.I590V (on ENST00000393238 / NM_001349268.2; = p.I266V on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV100260649; called by muse, mutect2, varscan2
- TNN | c.2810G>C p.S937T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV53434733; called by muse, mutect2
- TNNC2 | c.4-1G>T p.X2_splice | Splice Site (SNP) | VAF 39/114 reads (34%) | catalogued as COSV100999433; called by muse, mutect2, varscan2
- TNXB | c.6774G>T p.E2258D (on ENST00000647633; = p.E2011D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100925665; called by muse, mutect2, varscan2
- TOR1AIP2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.31); catalogued as rs1252153906, COSV100857245; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, varscan2
- TRIP12 | c.4082A>T p.Q1361L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99388965; called by muse, mutect2, varscan2
- TRMT9B | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV101501487; called by muse, mutect2, varscan2
- TSHZ3 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53677292, COSV99553158; called by muse, mutect2, varscan2
- TSPAN14 | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99627715; called by muse, mutect2, varscan2
- TSPY2 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.688); catalogued as COSV100289141; called by muse, mutect2, varscan2
- TTN | c.102298C>A p.P34100T (on ENST00000591111; = p.P26676T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | PolyPhen benign (0.033); catalogued as COSV100588448; called by muse, mutect2, varscan2
- TTN | c.26865T>G p.S8955R (on ENST00000591111; = p.S8028R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen benign (0.007); catalogued as COSV100588453; called by muse, mutect2, varscan2
- TYK2 | c.3177G>C p.E1059D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99313910; called by muse, mutect2, varscan2
- UBR4 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100919869; called by muse, mutect2, varscan2
- VANGL2 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100925502; called by muse, mutect2, varscan2
- VWC2 | c.809G>T p.C270F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61487351; called by muse, mutect2, varscan2
- WDR91 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60370358; called by muse, mutect2, varscan2
- WT1 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as CM041493, CM920718, CM982050, COSV60065677, COSV60065800, COSV60069955; called by muse, mutect2, varscan2
- XIRP2 | c.8048T>A p.I2683N (on ENST00000628543; = p.I2858N on NM_152381.6) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV99736662; called by muse, mutect2, varscan2
- ZCCHC13 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100272431; called by muse, mutect2
- ZDHHC15 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100973574; called by muse, mutect2, varscan2
- ZMIZ1 | c.2960C>T p.S987F | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100565792; called by muse, mutect2, varscan2
- ZNF117 | c.1142T>A p.I381K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99275055; called by muse, mutect2, varscan2
- ZNF180 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.136); catalogued as COSV99659513; called by muse, mutect2, varscan2
- ZNF208 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs559677640, COSV101236610, COSV68109260; called by muse, mutect2, varscan2
- ZNF215 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV99549049; called by muse, mutect2, varscan2
- ZNF235 | c.689A>T p.H230L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99349161; called by muse, mutect2, varscan2
- ZNF292 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60536476; called by muse, mutect2, varscan2
- ZNF423 | c.1574T>C p.F525S (on ENST00000563137 / NM_001379286.1; = p.F517S on NM_015069.4) | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs907699082, COSV99279133; called by muse, mutect2, varscan2
- ZNF548 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 30/46 reads (65%) | catalogued as COSV100277916; called by muse, mutect2, varscan2
- ZNF667 | c.33+1G>C p.X11_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99409894; called by muse, mutect2, varscan2
- ZNF676 | c.995A>T p.K332M (on ENST00000650058; = p.K300M on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101236065; called by muse, mutect2, varscan2
- ZSCAN18 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99558952; called by muse, mutect2, varscan2
- ATXN2L | c.2895+1dup | Frame Shift Ins (INS) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- BARD1 | c.387del p.S131Vfs*28 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- CRB1 | c.3102del p.W1034Cfs*4 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- GRK3 | c.830del p.X277_splice | Splice Site (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- LCA5 | c.1505del p.P502Qfs*91 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- MCM3AP | c.3430_3433dup p.R1145Tfs*10 | Frame Shift Ins (INS) | VAF 37/134 reads (28%) | called by mutect2, pindel, varscan2
- MUC16 | c.28983del p.I9662Sfs*22 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- NDST3 | c.1860del p.I621Sfs*97 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- NYAP2 | c.81del p.M28* | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- OR8H1 | c.295del p.Q99Rfs*25 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- PRKCB | c.290del p.D97Afs*34 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by pindel, varscan2
- SALL4 | c.2051A>C p.H684P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by mutect2, varscan2
- SLITRK3 | c.1061del p.G354Vfs*35 | Frame Shift Del (DEL) | VAF 40/193 reads (21%) | called by mutect2, pindel, varscan2
- ZNF473 | c.1760dup p.V588Sfs*5 | Frame Shift Ins (INS) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- ACTR1B | c.567C>T p.D189= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs770211908, COSV100007885; called by muse, mutect2, varscan2
- ADGRF5 | c.906G>A p.V302= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99344584; called by muse, mutect2, varscan2
- AKAP8 | c.789G>C p.G263= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99511613; called by muse, mutect2, varscan2
- ARHGAP36 | c.468A>G p.R156= | Silent (SNP) | VAF 48/64 reads (75%) | catalogued as COSV99357042; called by muse, mutect2, varscan2
- ATP13A4 | c.1041C>A p.L347= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV99793881; called by muse, mutect2, varscan2
- ATP1A3 | c.819C>A p.I273= (on ENST00000545399 / NM_001256214.2; = p.I260= on NM_152296.5) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100131767, COSV57486403, COSV57486962; called by muse, mutect2, varscan2
- BARX2 | c.60G>A p.R20= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV99858282; called by muse, mutect2, varscan2
- BAZ2A | c.4233C>A p.P1411= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99464274; called by muse, mutect2, varscan2
- BPIFB3 | c.1161G>T p.V387= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as COSV100972262; called by muse, mutect2, varscan2
- BRWD1 | c.6954T>C p.N2318= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs770913187, COSV100312566; called by muse, mutect2, varscan2
- CAPN9 | c.126G>A p.L42= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99679772, COSV99680022; called by muse, mutect2, varscan2
- CARMIL2 | c.1696C>T p.L566= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100575904, COSV58024613; called by muse, mutect2, varscan2
- CCDC181 | c.885A>C p.P295= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV100890213; called by muse, mutect2, varscan2
- CLIC5 | c.1107G>A p.E369= (on ENST00000185206 / NM_001370649.1; = p.E210= on NM_016929.5) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99483475; called by muse, mutect2, varscan2
- CNTNAP3 | c.2172T>C p.C724= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs749402212, COSV99903805; called by muse, mutect2
- CSGALNACT1 | c.639C>A p.I213= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100174356; called by muse, mutect2, varscan2
- CSMD2 | c.660G>T p.S220= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99584077; called by muse, mutect2, varscan2
- CTCFL | c.801T>C p.S267= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99711907; called by muse, mutect2, varscan2
- DHX8 | c.2889A>T p.T963= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99291778; called by muse, mutect2, varscan2
- DOCK2 | c.1416C>A p.P472= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99909441; called by muse, mutect2, varscan2
- DPH6 | c.69T>C p.A23= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99853085; called by muse, mutect2, varscan2
- DPPA4 | c.450G>A p.K150= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100169124; called by muse, mutect2, varscan2
- DSP | c.4767C>T p.C1589= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs763203149, COSV101131147; called by muse, mutect2, varscan2
- F5 | c.3792G>A p.Q1264= | Silent (SNP) | VAF 75/206 reads (36%) | catalogued as COSV100888809; called by muse, mutect2, varscan2
- FAM110B | c.495C>A p.V165= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100825935; called by muse, mutect2, varscan2
- FAM135B | c.2934T>G p.A978= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99417070; called by muse, mutect2, varscan2
- FLRT2 | c.1176C>T p.S392= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100419850; called by muse, mutect2, varscan2
- FZD7 | c.822C>G p.T274= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs1294938164, COSV99636678; called by muse, mutect2, varscan2
- GALNTL5 | c.45A>G p.T15= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101217602; called by muse, mutect2, varscan2
- GLI1 | c.3222C>A p.T1074= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs200550278, COSV99953523; called by muse, mutect2, varscan2
- GPA33 | c.432A>G p.P144= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100900851; called by muse, mutect2, varscan2
- GPR26 | c.336G>A p.L112= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99500694; called by muse, mutect2, varscan2
- GPR50 | c.669G>T p.G223= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as COSV99505415; called by muse, mutect2, varscan2
- HDC | c.972G>T p.L324= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV99983729; called by muse, mutect2, varscan2
- HGF | c.117T>A p.I39= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99735126; called by muse, mutect2, varscan2
- HTR7 | c.204C>A p.S68= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99518571; called by muse, mutect2, varscan2
- IFT140 | c.1425G>A p.R475= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV101276280; called by muse, mutect2, varscan2
- KCNC4 | c.909C>T p.C303= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV100873551; called by muse, mutect2, varscan2
- LCE2B | c.42C>T p.P14= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs1179338786, COSV100909249; called by muse, mutect2, varscan2
- LGALS3BP | c.1188C>G p.G396= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs771908669, COSV99431248; called by muse, mutect2, varscan2
- LRP1B | c.1908G>C p.R636= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV101249536, COSV67246433; called by muse, mutect2, varscan2
- LRRC3B | c.105C>A p.P35= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101185620; called by muse, mutect2, varscan2
- LRRIQ1 | c.1314C>T p.L438= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101279170; called by muse, mutect2, varscan2
- MUC4 | c.1929G>T p.P643= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV100638573, COSV62168079; called by muse, mutect2, varscan2
- MYO15A | c.102G>T p.S34= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99230580; called by muse, mutect2, varscan2
- NDRG2 | c.891G>T p.L297= (on ENST00000298687 / NM_001354570.1; = p.L283= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100068862; called by muse, mutect2, varscan2
- NDST3 | c.1065T>C p.H355= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs778631841, COSV99629168; called by muse, mutect2, varscan2
- NLRP5 | c.1501C>T p.L501= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV101173264; called by muse, mutect2, varscan2
- OLFML2A | c.717G>T p.V239= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV99992297; called by muse, mutect2, varscan2
- OR5AN1 | c.639A>G p.L213= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100004249; called by muse, mutect2, varscan2
- OR6K3 | c.342C>A p.I114= (on ENST00000368146; = p.I98= on NM_001005327.2) | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100933816; called by muse, mutect2, varscan2
- PCDH15 | c.5823C>A p.V1941= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100213071, COSV100227486; called by muse, mutect2, varscan2
- PDZRN3 | c.2400C>A p.A800= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs765599970, COSV99726730; called by muse, mutect2, varscan2
- POTEE | c.102C>T p.C34= | Silent (SNP) | VAF 55/186 reads (30%) | catalogued as COSV100386413, COSV58238821; called by muse, mutect2, varscan2
- PPP1CB | c.540A>G p.Q180= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99941633; called by muse, mutect2, varscan2
- RHOU | c.222C>T p.Y74= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs569745402, COSV100797154; called by muse, mutect2, varscan2
- SALL1 | c.741C>T p.I247= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs372297077; called by muse, mutect2, varscan2
- SCAF4 | c.2865G>A p.A955= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs373796708; called by muse, varscan2
- SELP | c.1671G>T p.S557= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99738665, COSV99739987; called by muse, mutect2, varscan2
- SERPINC1 | c.1047G>T p.V349= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV100874974; called by muse, mutect2, varscan2
- SLC28A1 | c.1542G>C p.G514= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as COSV99722280; called by muse, mutect2, varscan2
- SLC35F3 | c.231C>A p.I77= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs1210875557, COSV100784923; called by muse, mutect2, varscan2
- SLC41A2 | c.978A>T p.I326= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99315996; called by muse, mutect2, varscan2
- SLC6A5 | c.1347G>C p.G449= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100116126; called by muse, varscan2
- SLCO1B1 | c.1836A>T p.S612= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs370991447; called by muse, mutect2, varscan2
- SPEG | c.3339G>T p.R1113= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100402954; called by muse, mutect2, varscan2
- ST8SIA3 | c.43C>T p.L15= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1443087835, COSV100129209; called by muse, mutect2, varscan2
- TBC1D9 | c.3741G>T p.R1247= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs759291209, COSV101464239; called by muse, mutect2, varscan2
- TECTA | c.3867C>T p.A1289= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV50776003; called by muse, mutect2, varscan2
- THRB | c.345C>A p.T115= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99769158; called by muse, mutect2, varscan2
- TLR10 | c.1071T>C p.N357= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100457329; called by muse, mutect2, varscan2
- TMEM150B | c.288G>T p.L96= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100442171; called by muse, mutect2, varscan2
- TNP2 | c.81C>G p.T27= | Silent (SNP) | VAF 125/272 reads (46%) | catalogued as COSV100449478; called by muse, mutect2, varscan2
- TNRC18 | c.1515C>T p.G505= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs758047635, COSV101259295; called by muse, mutect2, varscan2
- TXNDC2 | c.1134A>G p.P378= (on ENST00000306084 / NM_001098529.2; = p.P311= on NM_032243.6) | Silent (SNP) | VAF 448/511 reads (88%) | catalogued as COSV100045609; called by muse, mutect2, varscan2
- UROC1 | c.987G>A p.L329= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99330582; called by muse, mutect2, varscan2
- USH2A | c.12744T>C p.H4248= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100227383; called by muse, mutect2, varscan2
- ZNF296 | c.15G>A p.K5= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV99541473; called by muse, mutect2, varscan2
- ZYG11B | c.813G>T p.L271= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99596602; called by muse, mutect2, varscan2
- CCNQP1 | n.217C>A | RNA (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- CCNQP1 | n.218C>A | RNA (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- ITGB1 | c.2331+1263C>G | Intron (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100171136; called by muse, mutect2, varscan2
- MELTF | c.712+1671G>A | Intron (SNP) | VAF 16/94 reads (17%) | catalogued as COSV99585650; called by muse, mutect2, varscan2
- RPL23AP42 | n.444T>A | RNA (SNP) | VAF 40/72 reads (56%) | called by muse, varscan2
- USH1C | c.1285-7686del | Intron (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
